Surgical pathology report (de-identified scan), TCGA case TCGA-VQ-AA6J, project TCGA-STAD (Stomach Adenocarcinoma), tissue source site Barretos Cancer Hospital, specimen TCGA-VQ-AA6J-01A (Primary Tumor).

[page 1 of 2]
Collect date:

ICD O-3
Adenocarcinoma, intestinal
type 8144/3
Site: Cardia NOS C16.0
Jt 3/20/14

PATHOLOGY REPORT:

PRIMARY SITE: Stomach (Cardia)

1 - "Product of total gastrectomy":

. Poorly differentiated adenocarcinoma, invasive and ulcerated, intestinal pattern of Laurén

. Tumor size: 5.0 x 4.0 x 1.5 cm

. Depth of infiltration: up to serosa

. Sanguineous vascular invasion: not detected

. Lymphatic vascular invasion: present

. Perineural invasion: present

. Adjacent mucosa: moderate chronic gastritis

. Surgical margins: free of neoplastic involvement

. 27 lymph nodes were dissected from peri-gastric fat, 3 of them are compromised by neoplasia (3/27), with capsular leakage, and distributed as follows:

- Chain 1 – right paracardiac: absence of lymphoid tissue

- Chain 2 - left paracardiac: 0/3

- Chain 3 – lesser curvature: absence of lymphoid tissue

- Chain 4 – greater curvature (4sa): absence of lymphoid tissue

- Chain 4 - along the left gastroepiploic vessels (4sb): 0/1

- Chain 4 - along the right gastroepiploic vessels (4d): 0/3

- Chain 5 - suprapyloric: absence of lymphoid tissue

- Chain 6 - infrapyloric: 0/3

- Chain 7 and 9 - left gastric artery and celiac trunk: 3/7

- Chain 8 - anterior hepatic artery (8a): 0/1

- Chain 8 - posterior hepatic artery (8p): 0/4

- Chain 11 - proximal splenic artery (11p): 0/5

2 - "Greater omentum":

. Free of neoplasia.

3 - "Esophageal margin":

. Free of neoplasia.

[page 2 of 2]
5 - "Proximal esophageal margin" (paraffin from frozen section):
. Free of neoplasia.

6 - " Lymph node from chain 6" (paraffin from frozen section):
. Free of neoplasia (0/1).

PATHOLOGIC STAGING

Topography	Morphology	Stage
Stomach, NOS	Adenocarcinoma, NOS	pT4 pN2

Criteria	12/23/13	Yes	No

Source: NCI Genomic Data Commons file d1afdfb1-41c2-4784-9a2f-4cc4f59ead62 (TCGA-VQ-AA6J.43D7E2EA-6FB7-4684-B647-B3503A746394.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).